Somatic mutation profile of tumor specimen TCGA-G9-7521-01A (aliquot TCGA-G9-7521-01A-11D-2260-08) from TCGA case TCGA-G9-7521, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 52.6 years (19,216 days).
Specimen TCGA-G9-7521-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 533c55d1-2434-4c63-826e-d9722fb17f9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-7521-10A (Blood Derived Normal), aliquot TCGA-G9-7521-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/322da509-6e1b-4dfa-8654-8ea615d09171

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, 5'Flank 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8625T>A p.N2875K | Missense Mutation (SNP) | VAF 24/99 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53753168; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP11 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV50298113; called by muse, mutect2, varscan2
- ARMC10 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1213297310, COSV60392686; called by muse, mutect2
- DSEL | c.2708C>A p.T903N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV59492637; called by muse, mutect2, varscan2
- MEFV | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs758868622, COSV54823911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MOSPD3 | c.187A>T p.T63S | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV56158424; called by muse, mutect2, varscan2
- MUC5AC | c.15076G>A p.V5026I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs772179907, COSV100611301; called by muse, varscan2
- OR2AG1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745849873, COSV56626367, COSV56626473; called by muse, mutect2, varscan2
- PSD | c.2192T>C p.V731A | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as COSV50048278; called by muse, mutect2, varscan2
- PSME3 | c.155T>G p.I52S | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.102); catalogued as COSV53199739; called by muse, mutect2, varscan2
- SMAD9 | c.1157A>G p.N386S (on ENST00000379826 / NM_001127217.3; = p.N349S on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs746974981, COSV63205410; called by muse, mutect2, varscan2
- TEAD1 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as COSV57566689; called by muse, mutect2, varscan2
- THEG | c.773C>A p.A258E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61074220; called by muse, mutect2, varscan2
- TMC8 | c.340C>G p.R114G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59209308, COSV59210327; called by muse, mutect2, varscan2
- USP30 | c.735T>G p.F245L | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV57449897; called by muse, mutect2, varscan2
- ZNF527 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as rs1459317357, COSV62231758; called by muse, mutect2, varscan2
- ZNF549 | c.1709C>T p.T570I (on ENST00000376233 / NM_001199295.2; = p.T557I on NM_153263.2) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs756138167, COSV53726271; called by muse, mutect2, varscan2
- BUD23 | c.822C>G p.G274= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV56095563; called by muse, mutect2, varscan2
- DNAH1 | c.7266C>A p.T2422= | Silent (SNP) | VAF 84/300 reads (28%) | catalogued as COSV70231187; called by muse, mutect2, varscan2
- MTCL1 | c.4212G>A p.E1404= (on ENST00000306329 / NM_001378206.1; = p.E1085= on NM_015210.4) | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs750833884, COSV60407848; called by muse, mutect2, varscan2
- NCAN | c.3588C>T p.N1196= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as rs761753453, COSV53053474; called by muse, mutect2, varscan2
- NSD1 | c.6603T>A p.S2201= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV61778652; called by muse, mutect2, varscan2
- PDPN | c.426C>T p.I142= (on ENST00000621990; = p.I218= on NM_006474.4) | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as rs1193024010, COSV53848148; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503535 C>G | 5'Flank (SNP) | VAF 13/114 reads (11%) | catalogued as rs1363447705; called by muse, mutect2, varscan2
- NKX2-4 | c.-2C>A | 5'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100698564; called by muse, mutect2, varscan2
- RN7SL176P | chr12:100157256 C>G | 3'Flank (SNP) | VAF 38/105 reads (36%) | catalogued as rs867169971; called by muse, mutect2, varscan2
